Somatic mutation profile of tumor specimen ALCH-B067-TTR1-A (aliquot ALCH-B067-TTR1-A-2-0-D-A80C-36) from ALCHEMIST case ALCH-B067, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.1 years (24,522 days).
Specimen ALCH-B067-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0268c0c-1311-49a9-86a8-6f8971c2d964.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B067-NB1-A (Blood Derived Normal), aliquot ALCH-B067-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07d743ce-ae7b-418d-a145-0b3fadb86e05

The open-access MAF lists 100 somatic variants for this specimen: 64 protein-altering or splice-affecting, 20 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 20, Intron 11, Nonsense Mutation 5, Frame Shift Del 5, 3'UTR 3, Splice Site 2, In Frame Ins 1, 5'Flank 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 198/401 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP002512.3 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54405810; called by muse, mutect2, varscan2
- APC2 | c.5606C>T p.A1869V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99279618; called by muse, mutect2, varscan2
- ATP8A1 | c.2440G>A p.V814I | Missense Mutation (SNP) | VAF 108/344 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.478); catalogued as rs560081854, COSV52531067; called by muse, mutect2, varscan2
- CBFA2T3 | c.1540C>A p.R514S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.823); catalogued as COSV51933331; called by muse, mutect2, varscan2
- CFAP47 | c.7760G>C p.S2587T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as rs16987461, COSV101074000; called by muse, mutect2, varscan2
- CIITA | c.3311C>T p.T1104M | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs367805896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTX1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs1273421124; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 68/449 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57515201; called by muse, mutect2, varscan2
- FAM90A27P | n.424+1G>T | Splice Site (SNP) | VAF 70/182 reads (38%) | catalogued as rs1301563642; called by muse, varscan2
- ICE1 | c.2717G>A p.G906E | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs769790339; called by muse, mutect2, varscan2
- KL | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs745808758, COSV101198958; called by muse, mutect2, varscan2
- KPNB1 | c.2353+1G>A p.X785_splice | Splice Site (SNP) | VAF 18/96 reads (19%) | catalogued as COSV51600941; called by muse, varscan2
- MRO | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199725891, COSV56497880; called by muse, mutect2, varscan2
- NADK | c.1335_1337dup p.G446dup | In Frame Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs765597263; called by mutect2, pindel
- NEBL | c.1449G>T p.E483D | Missense Mutation (SNP) | VAF 29/1025 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101009099; called by muse, mutect2
- PLPPR3 | c.959C>T p.S320L (on ENST00000520876 / NM_001270366.2; = p.S348L on NM_024888.2) | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs1246842705; called by muse, mutect2, varscan2
- PLXNA4 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs267601293, COSV58119180; called by muse, mutect2, varscan2
- RIMS2 | c.1771G>T p.G591* (on ENST00000666250 / NM_001348490.2; = p.G399* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 88/292 reads (30%) | catalogued as COSV51665503; called by muse, mutect2, varscan2
- SAMD9 | c.3554C>T p.S1185L | Missense Mutation (SNP) | VAF 187/713 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV66074598; called by muse, mutect2, varscan2
- SLC17A3 | c.914T>C p.I305T | Missense Mutation (SNP) | VAF 353/965 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as rs1415329000; called by muse, mutect2, varscan2
- SPATA31D1 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 200/478 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs376270710; called by muse, mutect2, varscan2
- TTN | c.78721A>G p.I26241V (on ENST00000591111; = p.I18817V on NM_003319.4) | Missense Mutation (SNP) | VAF 19/156 reads (12%) | PolyPhen benign (0.033); catalogued as rs548211686; called by muse, mutect2, varscan2
- TTYH2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138129824; called by muse, mutect2, varscan2
- ADAMTS16 | c.1426C>A p.R476S | Missense Mutation (SNP) | VAF 106/339 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C7orf50 | c.322A>T p.R108* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | called by mutect2, varscan2
- CARD6 | c.42_43del p.R15Kfs*5 | Frame Shift Del (DEL) | VAF 50/203 reads (25%) | called by mutect2, pindel, varscan2
- CAV3 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 185/601 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CDKN2A | c.32_42del p.P11Lfs*29 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel*
- CGREF1 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGR4 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- FASTKD3 | c.1726G>C p.G576R | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FRMD4B | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 151/468 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GDF1 | c.172del p.V58Ffs*108 | Frame Shift Del (DEL) | VAF 3/19 reads (16%) | called by mutect2, pindel
- GNA15 | c.463del p.H155Tfs*72 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by mutect2, pindel
- HERC2 | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 116/385 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- HFE | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 277/1285 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- HNRNPD | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 30/328 reads (9%) | called by muse, mutect2
- IFT80 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- KAT6A | c.4401G>C p.Q1467H | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LRRC32 | c.1733dup p.N578Kfs*42 | Frame Shift Ins (INS) | VAF 30/256 reads (12%) | called by mutect2, pindel, varscan2
- LYPD2 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 223/565 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- MBD2 | c.463del p.L155Sfs*10 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- MYBPC2 | c.2264T>A p.L755H | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NBAS | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 68/371 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NOTCH4 | c.4204C>A p.P1402T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.782); called by muse, varscan2
- P4HA3 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCSK1 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 97/226 reads (43%) | called by muse, mutect2, varscan2
- PICK1 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 72/537 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRDM7 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 73/334 reads (22%) | called by muse, mutect2, varscan2
- PTPRG | c.135C>A p.S45R | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RDH16 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 63/480 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RFC1 | c.314C>G p.T105R | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- RIMBP2 | c.2868A>T p.R956S | Missense Mutation (SNP) | VAF 73/511 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SELENOK | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SLC8A1 | c.491G>C p.G164A | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORCS1 | c.2359G>T p.A787S | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- SYT5 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.07); called by muse, mutect2
- TTN | c.13531T>A p.W4511R (on ENST00000591111; = p.W3584R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/186 reads (32%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXNIP | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 43/417 reads (10%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- WDR90 | c.4308C>A p.S1436R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ZNF672 | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ZP1 | c.1742C>A p.S581Y | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2
- ASTN1 | c.1065C>T p.N355= | Silent (SNP) | VAF 77/330 reads (23%) | catalogued as rs61758728; called by muse, mutect2, varscan2
- COL21A1 | c.2076G>T p.G692= | Silent (SNP) | VAF 150/571 reads (26%) | called by muse, mutect2, varscan2
- DPYSL2 | c.1686C>T p.P562= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs747715290, COSV60782498; called by muse, mutect2, varscan2
- EMSY | c.2856G>A p.Q952= | Silent (SNP) | VAF 201/527 reads (38%) | catalogued as COSV58263233, COSV58267045; called by muse, mutect2, varscan2
- ETV5 | c.756C>T p.V252= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- GCN1 | c.4758G>T p.T1586= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV56108423; called by muse, mutect2
- HERC2 | c.7155G>T p.L2385= | Silent (SNP) | VAF 41/319 reads (13%) | called by muse, mutect2, varscan2
- HNRNPA0 | c.537C>A p.I179= | Silent (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- KNL1 | c.1524G>A p.E508= (on ENST00000346991 / NM_170589.5; = p.E482= on NM_144508.5) | Silent (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- MS4A4E | c.795C>A p.P265= | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- NRXN2 | c.876C>T p.F292= | Silent (SNP) | VAF 124/314 reads (39%) | called by muse, varscan2
- NT5C3B | c.282C>T p.T94= | Silent (SNP) | VAF 12/215 reads (6%) | catalogued as rs532798148; called by muse, mutect2
- PA2G4 | c.300C>T p.L100= | Silent (SNP) | VAF 66/260 reads (25%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.157C>A p.R53= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV53853769; called by muse, mutect2, varscan2
- PHLDB3 | c.1497C>A p.T499= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, varscan2
- PLEC | c.4050C>T p.R1350= (on ENST00000322810 / NM_201380.4; = p.R1240= on NM_000445.5) | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as rs782293819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC17A5 | c.1374C>G p.T458= | Silent (SNP) | VAF 160/412 reads (39%) | called by muse, mutect2, varscan2
- SPATC1 | c.1629G>A p.A543= | Silent (SNP) | VAF 95/385 reads (25%) | catalogued as rs782374904; called by muse, mutect2, varscan2
- TPP2 | c.312A>C p.T104= | Silent (SNP) | VAF 53/255 reads (21%) | called by muse, mutect2, varscan2
- XKR4 | c.417C>T p.R139= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as rs371460599, COSV59310500; called by muse, mutect2, varscan2
- AC114490.3 | c.*512G>T | 3'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- ANXA8 | c.-171G>A | 5'UTR (SNP) | VAF 70/261 reads (27%) | catalogued as rs1332480769; called by muse, mutect2, varscan2
- ECPAS | chr9:111484491 C>T | 5'Flank (SNP) | VAF 13/24 reads (54%) | catalogued as rs777497339; called by muse, mutect2, varscan2
- ELMO2 | c.1884+196C>T | Intron (SNP) | VAF 66/252 reads (26%) | called by muse, mutect2, varscan2
- GRIK5 | c.2514+1017C>T | Intron (SNP) | VAF 94/275 reads (34%) | catalogued as COSV99490671; called by muse, mutect2, varscan2
- HARS2 | c.108+44C>A | Intron (SNP) | VAF 66/157 reads (42%) | called by muse, mutect2, varscan2
- HSD17B3 | c.672+19G>C | Intron (SNP) | VAF 193/490 reads (39%) | called by muse, mutect2, varscan2
- KCNIP2 | c.73+3739_73+3740delinsG | Intron (DEL) | VAF 55/245 reads (22%) | called by pindel, varscan2*
- KCTD15 | c.*222G>T | 3'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- MUCL3 | c.947-801G>T | Intron (SNP) | VAF 256/668 reads (38%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.52-49G>T | Intron (SNP) | VAF 28/248 reads (11%) | called by muse, mutect2, varscan2
- PCDH10 | c.*13G>C | 3'UTR (SNP) | VAF 80/333 reads (24%) | called by muse, mutect2, varscan2
- STIMATE | c.160+1370C>T | Intron (SNP) | VAF 33/289 reads (11%) | called by muse, mutect2, varscan2
- THRA | c.1110+29G>C | Intron (SNP) | VAF 37/279 reads (13%) | called by muse, mutect2, varscan2
- THRA | c.1110+30C>G | Intron (SNP) | VAF 34/276 reads (12%) | called by muse, varscan2
- TSPAN32 | c.627+76G>T | Intron (SNP) | VAF 47/113 reads (42%) | called by muse, mutect2, varscan2
